Somatic mutation profile of cancer-model specimen HCM-BROD-0874-C43-85N (Adherent Cell Line, passage 15; aliquot HCM-BROD-0874-C43-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0874-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.5 years (21,744 days).
Specimen HCM-BROD-0874-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e43709d-30d5-4e43-a5f0-5d9686a1812f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0874-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0874-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/509e712c-5ee1-4d82-8d69-e8fa2be90ef3

The open-access MAF lists 2,150 somatic variants for this specimen: 1,365 protein-altering or splice-affecting, 685 silent, 100 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,244, Silent 685, Nonsense Mutation 70, Intron 57, Splice Region 25, Frame Shift Del 13, 3'UTR 12, RNA 9, 3'Flank 8, 5'Flank 7, Splice Site 7, 5'UTR 7.

Variants (750 of 2,150; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.7681C>T p.Q2561* | Nonsense Mutation (SNP) | VAF 97/253 reads (38%) | catalogued as rs80358994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 326/326 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886248, CM052217; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 382/384 reads (99%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 77/174 reads (44%) | catalogued as rs727504301, CM033658; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 168/358 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2
- RIT1 | c.268A>G p.M90V | Missense Mutation (SNP) | VAF 341/341 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557960039, CM167019, COSV64170951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 79/319 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 263/374 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 202/309 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV50309213; called by muse, mutect2, varscan2
- ABCA13 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1436907195, COSV70033475; called by muse, mutect2, varscan2
- ABCA13 | c.11243G>A p.G3748E | Missense Mutation (SNP) | VAF 219/354 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV71285536; called by muse, mutect2, varscan2
- ABCA7 | c.5233C>T p.L1745F | Missense Mutation (SNP) | VAF 206/392 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CD166825, COSV99566241; called by muse, mutect2, varscan2
- AC100868.1 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 216/410 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as rs763542788; called by muse, mutect2, varscan2
- AC134980.2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs200194923, COSV100171580; called by mutect2, varscan2
- ACSM5 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs367648720; called by muse, mutect2, varscan2
- ACSS3 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs989417666, COSV54087157; called by muse, mutect2, varscan2
- ADAL | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 293/533 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs879198727; called by muse, mutect2, varscan2
- ADAM7 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.753); catalogued as COSV51541095; called by muse, mutect2, varscan2
- ADAMTS18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51424396; called by muse, mutect2, varscan2
- ADAMTS2 | c.2768G>A p.W923* | Nonsense Mutation (SNP) | VAF 109/365 reads (30%) | catalogued as rs1160288604; called by muse, mutect2, varscan2
- ADAR | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 484/485 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as rs1557888669; called by muse, mutect2, varscan2
- AL136295.1 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as rs752115104; called by muse, mutect2, varscan2
- ALAS2 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58189433; called by muse, mutect2, varscan2
- ALDH1L1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs760924764; called by muse, mutect2, varscan2
- ALLC | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 134/562 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1183049932; called by muse, mutect2
- ALMS1 | c.5785C>T p.R1929W | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs938557636; called by muse, mutect2, varscan2
- ALPL | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 169/468 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV100876209; called by muse, mutect2, varscan2
- ALS2CL | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 496/498 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs200941139, COSV59673499; called by muse, varscan2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 136/170 reads (80%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2, varscan2
- ANGEL1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 234/360 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747200123, COSV51873786; called by muse, mutect2, varscan2
- ANGPT4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 39/428 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1292675024; called by muse, mutect2
- ANK2 | c.8798C>T p.S2933F | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs771003489; called by muse, mutect2, varscan2
- ANK3 | c.10033G>A p.E3345K | Missense Mutation (SNP) | VAF 168/196 reads (86%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs759680076; called by mutect2, varscan2
- ANKFN1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 132/234 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs765917235; called by muse, mutect2, varscan2
- ANKIB1 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 81/124 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs547575488; called by muse, varscan2
- ANKRD30A | c.3379G>A p.E1127K (on ENST00000611781; = p.E1071K on NM_052997.2) | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV64616667; called by muse, mutect2, varscan2
- ANKRD30B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 393/394 reads (100%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.801); catalogued as COSV62811725; called by muse, mutect2, varscan2
- ANKRD31 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 211/302 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as COSV57163868; called by muse, mutect2, varscan2
- ANO3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV56780653; called by muse, mutect2, varscan2
- AOX1 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 96/376 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs756119874, COSV101022164; called by muse, mutect2, varscan2
- APBA1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 548/550 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1564062638, COSV55228003; called by muse, mutect2, varscan2
- APOB | c.12931G>A p.E4311K | Missense Mutation (SNP) | VAF 137/224 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV99265878; called by muse, mutect2, varscan2
- APOL5 | c.141C>T p.F47= | Splice Region (SNP) | VAF 498/641 reads (78%) | catalogued as rs757956930; called by muse, mutect2, varscan2
- ARHGAP36 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52265695; called by muse, mutect2, varscan2
- ARHGEF15 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 144/208 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs766671999; called by muse, mutect2, varscan2
- ARHGEF15 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201103318; called by muse, mutect2, varscan2
- ARHGEF5 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 97/754 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs761104506; called by muse, varscan2
- ARHGEF5 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 216/783 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV50218152, COSV99283276; called by muse, varscan2
- ARHGEF6 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs755130149; called by muse, varscan2
- ARHGEF6 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 316/318 reads (99%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.218); catalogued as COSV51687879, COSV51690842; called by muse, varscan2
- ARID4B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1212395172; called by muse, mutect2, varscan2
- ARL6IP4 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 543/543 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as rs1476805993; called by muse, mutect2, varscan2
- ASIC4 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 108/385 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1260516411; called by muse, mutect2, varscan2
- ASPHD2 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 142/698 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53218770; called by muse, mutect2, varscan2
- ASPM | c.9493C>T p.H3165Y | Missense Mutation (SNP) | VAF 324/325 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV99660147, COSV99661094; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ATAD3A | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 179/492 reads (36%) | catalogued as rs774681303; called by muse, mutect2
- ATN1 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 370/371 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as rs1555144090; called by muse, mutect2, varscan2
- ATP12A | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 251/359 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566077545, COSV54515540; called by muse, mutect2, varscan2
- ATP8A1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52548882; called by muse, mutect2, varscan2
- ATP8B1 | c.3040C>T p.R1014* | Nonsense Mutation (SNP) | VAF 291/291 reads (100%) | catalogued as rs781213892, CM043831, COSV52178820; called by muse, mutect2, varscan2
- BARX2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456206651, COSV55652434; called by muse, mutect2, varscan2
- BFSP1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 124/471 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.096); catalogued as rs755461021, COSV64901289; called by muse, mutect2
- BIRC3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs147996132; called by muse, mutect2, varscan2
- BIRC6 | c.3652C>T p.R1218C | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs776885767, COSV70205181; called by muse, mutect2, varscan2
- BMP5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 388/650 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702572; called by muse, varscan2
- BRINP3 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 448/449 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1399315630, COSV66519115; called by muse, mutect2, varscan2
- C17orf64 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756797485, COSV52258288; called by muse, mutect2, varscan2
- C1QTNF2 | c.137T>A p.M46K (on ENST00000393975; = p.M1? on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67432832; called by muse, mutect2, varscan2
- C2orf16 | c.5426C>T p.P1809L | Missense Mutation (SNP) | VAF 450/596 reads (76%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV62676386; called by muse, mutect2, varscan2
- C3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 244/396 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766179097; called by muse, mutect2, varscan2
- C6 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 141/229 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs867408360, COSV54706337; called by muse, mutect2, varscan2
- C7 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV57471178; called by muse, mutect2, varscan2
- C7 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1561262611; called by muse, mutect2, varscan2
- C7 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 153/323 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57470310, COSV57477578; called by muse, mutect2, varscan2
- CABIN1 | c.3077T>C p.L1026P | Missense Mutation (SNP) | VAF 437/579 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1405231047, COSV54078995; called by muse, mutect2, varscan2
- CACNA1F | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs371796154, COSV54294411, COSV99603155; called by muse, mutect2, varscan2
- CACNA1G | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs1223904275; called by muse, mutect2, varscan2
- CACNA1G | c.3249G>A p.M1083I | Missense Mutation (SNP) | VAF 89/331 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs777415638, COSV61724421; called by muse, mutect2, varscan2
- CACNA1H | c.6239C>T p.S2080F | Missense Mutation (SNP) | VAF 821/827 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as COSV52356109; called by muse, mutect2, varscan2
- CACNA2D1 | c.2248G>A p.E750K (on ENST00000356253 / NM_001366867.1; = p.E738K on NM_000722.4) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV62397243; called by muse, mutect2, varscan2
- CACNG2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 76/453 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100268446; called by muse, mutect2, varscan2
- CADPS | c.3555C>T p.F1185= | Splice Region (SNP) | VAF 103/103 reads (100%) | catalogued as rs770554516, COSV51894992; called by muse, mutect2, varscan2
- CAGE1 | c.1279G>A p.E427K (on ENST00000512086; = p.E291K on NM_205864.3) | Missense Mutation (SNP) | VAF 204/573 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1465298705; called by muse, mutect2, varscan2
- CALHM1 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 460/460 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324349; called by muse, mutect2, varscan2
- CATSPERB | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 181/601 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs1215491838, COSV56426370; called by muse, mutect2, varscan2
- CATSPERB | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 141/433 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830647; called by muse, mutect2, varscan2
- CCDC142 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 448/543 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51779697; called by muse, varscan2
- CCDC168 | c.14791G>A p.E4931K | Missense Mutation (SNP) | VAF 161/309 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs1439993263; called by muse, mutect2, varscan2
- CCDC182 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 341/489 reads (70%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.384); catalogued as rs750904613; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 78/102 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CD163L1 | c.1928G>A p.G643E | Missense Mutation (SNP) | VAF 366/366 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58011409; called by muse, mutect2, varscan2
- CD207 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 315/401 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101338585; called by muse, mutect2, varscan2
- CD33 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 162/453 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV51800032; called by muse, mutect2, varscan2
- CD96 | c.947G>A p.G316E (on ENST00000283285 / NM_198196.3; = p.G300E on NM_005816.5) | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV51916437; called by muse, varscan2
- CDH9 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 163/278 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50370647, COSV50459979; called by muse, mutect2, varscan2
- CDK12 | c.4372C>T p.H1458Y (on ENST00000447079 / NM_016507.4; = p.H1449Y on NM_015083.3) | Missense Mutation (SNP) | VAF 156/497 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV71001445; called by muse, mutect2, varscan2
- CDK8 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 158/432 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs756268970, COSV67423737; called by muse, mutect2, varscan2
- CDKN2A | c.300del p.A102Rfs*44 | Frame Shift Del (DEL) | VAF 570/950 reads (60%) | catalogued as COSV58691635; called by pindel, varscan2
- CDYL2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 399/401 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV73654957; called by muse, mutect2, varscan2
- CEACAM4 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 253/453 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV99701031; called by muse, mutect2, varscan2
- CEACAM7 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99137365; called by muse, mutect2, varscan2
- CECR2 | c.671C>T p.S224F (on ENST00000342247 / NM_001290047.2; = p.S61F on NM_001290046.1) | Missense Mutation (SNP) | VAF 392/500 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV52849627; called by muse, mutect2, varscan2
- CELF6 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 159/454 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs769547615, COSV54715476; called by muse, mutect2, varscan2
- CFAP20DC | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 426/426 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1377040246; called by muse, mutect2, varscan2
- CFAP221 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 255/372 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99732367; called by muse, mutect2, varscan2
- CFAP47 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52884843, COSV52891359; called by muse, mutect2, varscan2
- CFAP47 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 242/243 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV52881110; called by muse, mutect2, varscan2
- CFAP54 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs879737066; called by muse, mutect2
- CFAP74 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 198/688 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566104; called by muse, mutect2, varscan2
- CFAP99 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 99/612 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs778653308; called by muse, mutect2, varscan2
- CFHR5 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 358/360 reads (99%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs890060392, COSV56819542; called by muse, mutect2, varscan2
- CFTR | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.902); catalogued as CM003234; called by muse, mutect2, varscan2
- CFTR | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs144720913, CM067769, COSV50060609, COSV50129630; called by muse, mutect2, varscan2
- CHRM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 400/642 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768531848, COSV57767335, COSV57769152; called by muse, mutect2, varscan2
- CHRNA6 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 303/448 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775552140, COSV99373299; called by muse, mutect2, varscan2
- CLCN1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 285/381 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV58368220; called by muse, mutect2, varscan2
- CLEC5A | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 265/375 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV101407799; called by muse, mutect2, varscan2
- CLVS1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 247/431 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV100370801; called by muse, mutect2, varscan2
- CLVS2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV51562421; called by muse, mutect2, varscan2
- CMYA5 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV71410348; called by muse, mutect2, varscan2
- CNGA1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs769046389, COSV62055358; called by muse, mutect2, varscan2
- CNGA3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 259/368 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs749949335; called by muse, mutect2, varscan2
- CNTNAP2 | c.1715C>T p.T572I | Missense Mutation (SNP) | VAF 332/450 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100668586; called by muse, mutect2, varscan2
- COL11A2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 163/858 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs764076227, COSV100554553; called by muse, mutect2, varscan2
- COL14A1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 270/482 reads (56%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); catalogued as rs1317268989, COSV52858084; called by muse, mutect2, varscan2
- COL14A1 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1316632101; called by muse, mutect2, varscan2
- COL1A2 | c.3281C>T p.P1094L | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV51964923; called by muse, mutect2, varscan2
- COL21A1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 215/543 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs771765654, COSV55156257; called by muse, mutect2, varscan2
- COL21A1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 472/819 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1009121320, COSV55158368; called by muse, mutect2, varscan2
- COL4A2 | c.4358G>A p.G1453E | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64634165; called by muse, mutect2, varscan2
- COL4A3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416146; called by muse, mutect2, varscan2
- COL4A4 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 199/304 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014563; called by muse, mutect2, varscan2
- COL5A2 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 237/314 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768322852, COSV66411238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV55201496; called by muse, mutect2, varscan2
- COL8A1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 339/339 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99658683; called by muse, mutect2, varscan2
- CPA4 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55984132, COSV55985226; called by muse, mutect2, varscan2
- CPA4 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 72/530 reads (14%) | catalogued as rs774692846; called by muse, mutect2, varscan2
- CPHXL | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 468/469 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1215439491; called by muse, mutect2, varscan2
- CPNE3 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 159/387 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52207655; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CREB1 | c.454G>A p.E152K (on ENST00000432329 / NM_134442.5; = p.E138K on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62066518; called by muse, mutect2, varscan2
- CRYBG1 | c.3406C>T p.P1136S | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64813921; called by muse, mutect2, varscan2
- CSF2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 125/239 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs747150863; called by muse, mutect2, varscan2
- CSMD2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 328/522 reads (63%) | catalogued as rs867259644, COSV53934021; called by muse, mutect2, varscan2
- CSMD3 | c.10390C>T p.P3464S (on ENST00000297405 / NM_001363185.1; = p.P3295S on NM_052900.3) | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141126792, COSV52122184; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CTNNA2 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 244/329 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58155619; called by muse, mutect2, varscan2
- CTNND2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.03); catalogued as COSV58889602; called by muse, mutect2, varscan2
- CXorf58 | c.857G>C p.R286P | Missense Mutation (SNP) | VAF 388/389 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64858744; called by muse, mutect2, varscan2
- CYP11A1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 167/419 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779269933, COSV51432107; called by muse, mutect2, varscan2
- CYP2C19 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 348/349 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs867860347, COSV64908478, COSV64909232; called by muse, mutect2, varscan2
- CYP2D6 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 254/1720 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs748519122; called by muse, varscan2
- CYP2W1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 234/396 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1441933750; called by muse, mutect2, varscan2
- CYP4A22 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 265/683 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1485938745, COSV53741605; called by muse, mutect2, varscan2
- CYP4F3 | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894963953, COSV55408197; called by muse, mutect2, varscan2
- CYTH4 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 383/502 reads (76%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs868185751, COSV50634225; called by muse, mutect2, varscan2
- DAPP1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.011); catalogued as COSV56453702; called by muse, mutect2, varscan2
- DBF4B | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 202/632 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142562446, COSV59260243; called by muse, mutect2, varscan2
- DCAF17 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 223/323 reads (69%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1223919095; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DCLRE1B | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 294/425 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs747277233; called by muse, mutect2, varscan2
- DEFB115 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 382/526 reads (73%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV68723046; called by muse, mutect2, varscan2
- DENND2C | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs887055482; called by muse, mutect2, varscan2
- DHX16 | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 669/835 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV64565886; called by muse, mutect2, varscan2
- DLEC1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 276/277 reads (100%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV57307670; called by muse, mutect2, varscan2
- DLG2 | c.2131C>T p.H711Y | Missense Mutation (SNP) | VAF 62/62 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV104381757; called by muse, mutect2, varscan2
- DNAH5 | c.13487G>A p.R4496Q | Missense Mutation (SNP) | VAF 136/242 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs759999227, COSV99454092; called by muse, mutect2, varscan2
- DNAJB7 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 611/801 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99344320; called by muse, mutect2, varscan2
- DOCK10 | c.2131A>G p.K711E | Missense Mutation (SNP) | VAF 249/377 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as rs1268565057; called by muse, mutect2, varscan2
- DOCK6 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 274/575 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs745904472; called by muse, mutect2, varscan2
- DPYD | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 254/612 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594494; called by muse, mutect2, varscan2
- DRAXIN | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 191/536 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99610545; called by muse, varscan2
- DSC3 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV64573151; called by muse, varscan2
- DSCAM | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 163/164 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV68031123; called by muse, mutect2, varscan2
- DSCAM | c.2787G>A p.W929* | Nonsense Mutation (SNP) | VAF 161/161 reads (100%) | catalogued as COSV68032759; called by muse, mutect2, varscan2
- DSG1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 329/329 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs770916767, COSV57134860; called by muse, mutect2, varscan2
- DSG1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 485/485 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57133213; called by muse, mutect2, varscan2
- DSG1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 478/478 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs749203049; called by muse, mutect2, varscan2
- DSG1 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 359/359 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs778003137, COSV57134002; called by muse, mutect2, varscan2
- DSP | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as COSV65790764; called by muse, mutect2, varscan2
- DST | c.13363G>A p.V4455I (on ENST00000361203 / NM_001374722.1; = p.V2043I on NM_015548.5) | Missense Mutation (SNP) | VAF 232/437 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV55038669; called by muse, mutect2, varscan2
- DVL1 | c.2008C>T p.P670S (on ENST00000378888 / NM_001330311.2; = p.P645S on NM_004421.3) | Missense Mutation (SNP) | VAF 627/1009 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs779009859; called by muse, mutect2, varscan2
- EHMT1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 361/362 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs532880924, COSV58373626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK4 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 236/449 reads (53%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.995); catalogued as COSV55465653; called by muse, mutect2, varscan2
- EIF4A3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs753145766; called by muse, mutect2, varscan2
- EIF4G1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 456/465 reads (98%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as rs1300223766; called by muse, varscan2
- ELF2 | c.367C>T p.P123S (on ENST00000379550 / NM_001331036.2; = p.P63S on NM_006874.4) | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs772288725; called by muse, mutect2, varscan2
- ELF4 | c.1889G>C p.S630T | Missense Mutation (SNP) | VAF 426/426 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV57453998; called by muse, varscan2
- ELF5 | c.731G>A p.R244Q (on ENST00000312319 / NM_198381.2; = p.R234Q on NM_001422.4) | Missense Mutation (SNP) | VAF 192/252 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143099997; called by muse, mutect2, varscan2
- EPHA3 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 397/399 reads (99%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV60709250, COSV60725648; called by muse, mutect2, varscan2
- EPHA4 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56029317; called by muse, mutect2, varscan2
- EPHA8 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 238/721 reads (33%) | catalogued as rs1272570562, COSV51263859; called by muse, mutect2, varscan2
- ERBB3 | c.3100C>T p.P1034S | Missense Mutation (SNP) | VAF 272/275 reads (99%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs748965595; called by muse, mutect2, varscan2
- ERICH3 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 280/466 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100444943; called by muse, mutect2
- ERVMER34-1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 102/528 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1162419277; called by muse, mutect2, varscan2
- ESPNL | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 207/207 reads (100%) | catalogued as COSV54544546; called by muse, mutect2, varscan2
- EVX1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 300/590 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as rs776053650; called by muse, mutect2, varscan2
- FAM120C | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV60258709; called by muse, mutect2, varscan2
- FAM124B | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 135/461 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs972144765; called by muse, mutect2, varscan2
- FAM170A | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV58924267; called by muse, mutect2, varscan2
- FAM180A | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 130/863 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1412266948; called by muse, mutect2, varscan2
- FAM83B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 249/651 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60920165; called by muse, mutect2, varscan2
- FAM83B | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 276/727 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV60922315; called by muse, mutect2, varscan2
- FAM83B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 183/545 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs766774691, COSV60919265; called by muse, mutect2, varscan2
- FANCD2 | c.3527A>G p.N1176S | Missense Mutation (SNP) | VAF 341/341 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764205355; called by muse, mutect2, varscan2
- FAT3 | c.8939G>A p.S2980N | Missense Mutation (SNP) | VAF 123/124 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53177923; called by muse, mutect2, varscan2
- FAT4 | c.11389G>A p.G3797R | Missense Mutation (SNP) | VAF 351/352 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1218915760, COSV100626803, COSV58673045, COSV58704036; called by muse, mutect2, varscan2
- FBN1 | c.1959T>A p.V653= | Splice Region (SNP) | VAF 122/324 reads (38%) | catalogued as rs1259303204; called by mutect2, varscan2
- FBN3 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs749453532, COSV54455724; called by muse, mutect2
- FBN3 | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 143/262 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs147529451; called by muse, mutect2, varscan2
- FBXO42 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 427/722 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs748281060, COSV65046929; called by muse, mutect2, varscan2
- FCGR1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 278/323 reads (86%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs781880153; called by muse, mutect2, varscan2
- FCN1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV65662719; called by muse, mutect2, varscan2
- FCN3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 217/634 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54640803; called by muse, mutect2, varscan2
- FCRL5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 492/494 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs763929627, COSV62513493; called by muse, mutect2, varscan2
- FFAR4 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 521/521 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141464588; called by muse, mutect2, varscan2
- FLG | c.11267A>C p.D3756A | Missense Mutation (SNP) | VAF 680/681 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.472); catalogued as COSV64245288; called by muse, mutect2, varscan2
- FLG2 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 417/417 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs746819915, COSV66166799; called by muse, mutect2, varscan2
- FLT1 | c.2159G>A p.R720K | Missense Mutation (SNP) | VAF 152/261 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56734332; called by muse, mutect2, varscan2
- FMN2 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 501/501 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142687; called by muse, mutect2, varscan2
- FOXA1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 222/844 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV51648233; called by muse, mutect2
- FOXA3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 184/436 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100141509; called by muse, mutect2, varscan2
- FOXN1 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752558563; called by muse, mutect2, varscan2
- FOXR1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57653553; called by muse, mutect2, varscan2
- FRA10AC1 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV63272379; called by mutect2, varscan2
- FRAS1 | c.8182G>A p.G2728S | Missense Mutation (SNP) | VAF 343/343 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs915414147, COSV99347117; called by muse, mutect2, varscan2
- FRAS1 | c.9040C>T p.L3014F | Missense Mutation (SNP) | VAF 336/338 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV53623835; called by muse, mutect2, varscan2
- FSD2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 287/501 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58008746; called by muse, mutect2, varscan2
- FSTL5 | c.959C>G p.T320S | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV60229680; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 438/443 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, varscan2
- GABRB2 | c.1499C>T p.S500F (on ENST00000274547; = p.S462F on NM_000813.3) | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as COSV50903913; called by muse, mutect2, varscan2
- GABRB3 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 174/447 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1220761805, COSV54661057; called by muse, mutect2, varscan2
- GALC | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 151/428 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV54323724; called by muse, mutect2, varscan2
- GBA3 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as rs1369441971, COSV72438254, COSV72438766; called by muse, mutect2, varscan2
- GCAT | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 361/430 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780863430; called by muse, mutect2, varscan2
- GIMAP8 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 494/653 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV56231157; called by muse, mutect2, varscan2
- GK2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62628049; called by muse, mutect2, varscan2
- GLB1L3 | c.1832G>A p.W611* | Nonsense Mutation (SNP) | VAF 114/115 reads (99%) | catalogued as COSV101345138; called by muse, mutect2, varscan2
- GLT6D1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 542/542 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1158461483; called by muse, mutect2, varscan2
- GPHN | c.1690C>T p.R564C (on ENST00000315266 / NM_001377519.1; = p.R597C on NM_020806.5) | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1360125120, COSV104400759; called by muse, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GPR65 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 239/616 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as rs558039201; called by muse, mutect2, varscan2
- GPRIN2 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 332/645 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65402916; called by muse, mutect2, varscan2
- GPRIN2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs782738328, COSV65401181; called by muse, mutect2, varscan2
- GRHL2 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs766515922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIA1 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.138); catalogued as rs1340594187; called by muse, mutect2, varscan2
- GRM6 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 162/267 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1185965317; called by muse, mutect2, varscan2
- GRXCR2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs447402, COSV65060697; called by muse, mutect2, varscan2
- GSAP | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs370849463; called by muse, mutect2, varscan2
- GTPBP10 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 130/200 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1013329253; called by muse, mutect2, varscan2
- GYS2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 336/336 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs376712209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H6PD | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 308/539 reads (57%) | catalogued as rs1438111258; called by mutect2, varscan2
- HCN1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 336/607 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57514706; called by muse, varscan2
- HDC | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 184/337 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs749851294, COSV51068330; called by muse, mutect2, varscan2
- HDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 237/447 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367618872, COSV51070116; called by muse, mutect2, varscan2
- HEATR4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 171/455 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866192463; called by muse, mutect2, varscan2
- HEPACAM2 | c.587C>T p.S196F (on ENST00000394468 / NM_001039372.4; = p.S184F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/299 reads (64%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); catalogued as COSV59063373; called by muse, mutect2, varscan2
- HMCN1 | c.14362C>T p.P4788S | Missense Mutation (SNP) | VAF 434/435 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV54899297; called by muse, mutect2, varscan2
- HNRNPCL1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 198/547 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.342); catalogued as rs1455984178; called by muse, mutect2, varscan2
- HOMEZ | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs200890395; called by muse, mutect2, varscan2
- HOXB8 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 375/590 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs749106433; called by muse, mutect2, varscan2
- HPSE | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 448/448 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183947666; called by muse, varscan2
- HRAS | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54238391, COSV54244417; called by muse, mutect2, varscan2
- HSD11B1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 552/553 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54829522; called by muse, mutect2, varscan2
- HSF5 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 294/447 reads (66%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.005); catalogued as rs1450375404; called by muse, mutect2, varscan2
- HTR1E | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 350/351 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552106885; called by muse, mutect2, varscan2
- HYDIN | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV66636846, COSV66638877; called by muse, mutect2, varscan2
- HYDIN | c.7063G>A p.E2355K | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV59253270; called by mutect2, varscan2
- IFI44L | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 149/408 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV60726789; called by muse, mutect2, varscan2
- IGF1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV61031622, COSV61033552; called by muse, mutect2, varscan2
- IGHA1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 250/598 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1286596126; called by muse, mutect2, varscan2
- IGHV3-48 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 146/329 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as rs781906099; called by muse, mutect2, varscan2
- IGLON5 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 121/378 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1360349755; called by muse, mutect2, varscan2
- IHH | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 162/552 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV55393786; called by muse, varscan2
- IL1RAPL1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 497/498 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199864130, COSV56250433; called by muse, mutect2, varscan2
- IL1RL1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 280/446 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs150294315; called by muse, mutect2
- IL31 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756327888, COSV65476689; called by muse, mutect2, varscan2
- IL36B | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 113/508 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52086453; called by muse, mutect2, varscan2
- INTS6L | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 200/200 reads (100%) | catalogued as COSV66085998; called by muse, mutect2, varscan2
- IQSEC3 | c.1157C>T p.S386F (on ENST00000538872 / NM_001170738.2; = p.S83F on NM_015232.1) | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1221691608, COSV100407780, COSV58288922; called by muse, mutect2, varscan2
- IRF5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 284/380 reads (75%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV50859233; called by muse, mutect2, varscan2
- IRS2 | c.2929G>A p.D977N | Missense Mutation (SNP) | VAF 199/670 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs751311445; called by muse, mutect2, varscan2
- ITFG1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 456/458 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as rs527980093; called by muse, mutect2, varscan2
- IVL | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 216/383 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as COSV64215570; called by muse, varscan2
- IVL | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 583/587 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1410895544; called by muse, mutect2, varscan2
- IWS1 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767140; called by muse, mutect2, varscan2
- KANK4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1485212258, COSV62985916; called by muse, mutect2, varscan2
- KAT2A | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 165/454 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV56789548; called by muse, mutect2, varscan2
- KATNBL1 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.13); catalogued as COSV56623134, COSV56626046; called by muse, mutect2, varscan2
- KBTBD7 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs140042626; called by muse, mutect2, varscan2
- KCNB2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 251/495 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs866484467, COSV73051743; called by muse, mutect2, varscan2
- KCNB2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 234/418 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV73050743; called by mutect2, varscan2
- KCND2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 167/253 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582688; called by muse, mutect2, varscan2
- KCNK1 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 497/499 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64036358; called by muse, mutect2, varscan2
- KCNN1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 357/766 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as COSV55838443; called by muse, mutect2, varscan2
- KCTD8 | c.1200G>A p.W400* | Nonsense Mutation (SNP) | VAF 97/601 reads (16%) | catalogued as COSV63593626; called by muse, mutect2, varscan2
- KDM1A | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327361293; called by muse, mutect2, varscan2
- KEL | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 136/549 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1215806158; called by muse, mutect2, varscan2
- KHSRP | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 302/520 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV67919459; called by muse, mutect2, varscan2
- KIAA1210 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 236/238 reads (99%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775653483, COSV68175814; called by muse, mutect2, varscan2
- KIAA1671 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 152/751 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV104422068; called by muse, mutect2, varscan2
- KIF16B | c.1782C>T p.P594= | Splice Region (SNP) | VAF 179/240 reads (75%) | catalogued as rs780867035; called by muse, mutect2, varscan2
- KIF1C | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs555256113, COSV57905880; called by muse, mutect2, varscan2
- KIF1C | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 102/499 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.122); catalogued as rs763684173; called by muse, mutect2, varscan2
- KIF2B | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 252/384 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1479558414, COSV52127285; called by muse, mutect2, varscan2
- KIR2DL1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1392775546; called by muse, mutect2, varscan2
- KIR2DS4 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 117/307 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs530424690; called by muse, mutect2, varscan2
- KIRREL1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 422/422 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs1296999444, COSV63292457; called by muse, mutect2, varscan2
- KLC4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 399/581 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs756928667, COSV52434917; called by muse, mutect2, varscan2
- KLF8 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 365/365 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100808452; called by muse, mutect2, varscan2
- KLHL1 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 119/189 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99060882; called by muse, mutect2, varscan2
- KLHL34 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 410/411 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs148422098; called by muse, mutect2, varscan2
- KMT2A | c.6310G>T p.E2104* | Nonsense Mutation (SNP) | VAF 77/77 reads (100%) | catalogued as COSV100630037; called by muse, mutect2, varscan2
- KMT2B | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55867018; called by muse, mutect2, varscan2
- KMT2B | c.5743C>T p.R1915C | Missense Mutation (SNP) | VAF 386/685 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1471456268; called by muse, mutect2, varscan2
- KRT10 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 449/684 reads (66%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.989); catalogued as rs774951544; called by muse, mutect2, varscan2
- KRT33B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 225/623 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1210131504; called by muse, mutect2, varscan2
- LAMA2 | c.7811G>A p.R2604Q | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs200853002, COSV104436759; called by muse, mutect2, varscan2
- LAMA5 | c.3736C>T p.L1246F | Missense Mutation (SNP) | VAF 175/750 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1201553411; called by muse, mutect2, varscan2
- LARP1B | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs759640074, COSV99218598; called by muse, mutect2, varscan2
- LCOR | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1371587683; called by muse, mutect2, varscan2
- LCOR | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 345/345 reads (100%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.897); catalogued as rs1239242490; called by muse, mutect2, varscan2
- LFNG | c.1123C>T p.R375C (on ENST00000222725 / NM_001040167.2; = p.R246C on NM_002304.2) | Missense Mutation (SNP) | VAF 231/416 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs746683505, COSV56069552; called by muse, mutect2, varscan2
- LIFR | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 212/452 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746053471, COSV54686247; called by muse, mutect2, varscan2
- LILRA1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 226/570 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs150040624; called by muse, varscan2
- LILRA1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 205/477 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs367952905; called by muse, mutect2, varscan2
- LILRA2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 270/1080 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs770183945, COSV52191773; called by muse, mutect2, varscan2
- LLCFC1 | c.228C>T p.D76= (on ENST00000458732; = p.D45= on NM_178829.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 97/449 reads (22%) | catalogued as rs1372851052; called by muse, mutect2, varscan2
- LOXL2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99743673; called by muse, mutect2, varscan2
- LRP5 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 52/659 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM153247, COSV53720975; called by muse, mutect2
- LRRC53 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs186092838; called by mutect2, varscan2
- LRRC63 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1189295066; called by muse, mutect2, varscan2
- LRRC7 | c.329G>A p.R110Q (on ENST00000651989 / NM_001370785.2; = p.R77Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/180 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs267598703, COSV50462590; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 538/538 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- LRRTM4 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139355; called by muse, mutect2
- LRRTM4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV69139163; called by muse, mutect2, varscan2
- LTBP2 | c.4761G>A p.W1587* | Nonsense Mutation (SNP) | VAF 255/395 reads (65%) | catalogued as COSV56205787; called by muse, mutect2, varscan2
- LTBP2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 234/664 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs751582703; called by muse, mutect2, varscan2
- MACC1 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 220/441 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV60540760; called by muse, mutect2, varscan2
- MAGEA10 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 360/362 reads (99%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.891); catalogued as rs766302328; called by mutect2, varscan2
- MAGEC1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 327/350 reads (93%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.86); catalogued as COSV53579372; called by muse, mutect2, varscan2
- MAGI3 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 283/415 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776665703, COSV100289112; called by muse, mutect2, varscan2
- MAMDC2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 402/402 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs368297806; called by muse, mutect2, varscan2
- MAP3K5 | c.3514C>T p.P1172S | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62887558; called by muse, mutect2, varscan2
- MAPK3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 394/395 reads (100%) | catalogued as COSV99531924; called by muse, mutect2, varscan2
- MARK1 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 319/319 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs745932586, COSV100857307; called by muse, mutect2, varscan2
- MCCD1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 78/487 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs772597720; called by muse, mutect2, varscan2
- MCMDC2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 149/294 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs772048792, COSV58037223; called by muse, mutect2, varscan2
- MCOLN1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 170/303 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51176800; called by muse, mutect2, varscan2
- MCTP1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs200443526; called by muse, mutect2, varscan2
- MCUR1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs767442278, COSV100848922; called by muse, mutect2, varscan2
- MED13 | c.3628C>T p.P1210S | Missense Mutation (SNP) | VAF 156/458 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs759251419; called by muse, mutect2, varscan2
- MEGF10 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 138/235 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57249059; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 378/488 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, varscan2
- MGAM2 | c.5875G>A p.D1959N | Missense Mutation (SNP) | VAF 185/891 reads (21%) | SIFT tolerated, low confidence (0.75); catalogued as rs963233882; called by muse, mutect2, varscan2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- MICAL2 | c.4418C>T p.S1473F | Missense Mutation (SNP) | VAF 288/374 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as rs374774096; called by muse, mutect2, varscan2
- MINDY4 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 182/362 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs536283558; called by muse, mutect2, varscan2
- MKI67 | c.3812G>A p.R1271K | Missense Mutation (SNP) | VAF 468/470 reads (100%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.579); catalogued as rs765282623, COSV64075463; called by muse, mutect2, varscan2
- MN1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 853/1115 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV56555852; called by muse, mutect2, varscan2
- MNX1 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 202/658 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.083); catalogued as rs992402696, COSV53318101, COSV99429836; called by muse, mutect2, varscan2
- MROH2B | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 158/322 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV101270772; called by muse, mutect2, varscan2
- MROH6 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 550/972 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.386); catalogued as rs1051555447; called by muse, mutect2, varscan2
- MRPL38 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs371715586; called by muse, mutect2, varscan2
- MS4A1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210730619, COSV100619266, COSV61941897; called by muse, mutect2, varscan2
- MTIF2 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 77/458 reads (17%) | catalogued as rs781465997, COSV55053308; called by muse, mutect2, varscan2
- MTOR | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 460/750 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1313381757, COSV63868827, COSV63869329; called by muse, mutect2, varscan2
- MUC16 | c.37640C>T p.T12547I | Missense Mutation (SNP) | VAF 131/272 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs545429785, COSV67447770; called by muse, mutect2, varscan2
- MUC16 | c.27068C>T p.P9023L | Missense Mutation (SNP) | VAF 250/487 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); catalogued as COSV67446839; called by muse, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 197/377 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC16 | c.17269G>A p.D5757N | Missense Mutation (SNP) | VAF 178/335 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.917); catalogued as rs910009324, COSV67477126; called by muse, mutect2, varscan2
- MUC16 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 240/429 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs375187648, COSV101198066, COSV104432151; called by muse, varscan2
- MUC16 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 220/458 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs369271832; called by muse, mutect2, varscan2
- MUC16 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 208/424 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV67442269; called by muse, mutect2, varscan2
- MUC17 | c.6091G>A p.G2031S | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs1310896897; called by muse, mutect2, varscan2
- MUC17 | c.11198C>T p.S3733L | Missense Mutation (SNP) | VAF 160/260 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60296811; called by muse, mutect2, varscan2
- MUTYH | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 274/476 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs773108803, COSV58344939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.4374C>T p.I1458= | Splice Region (SNP) | VAF 38/179 reads (21%) | catalogued as COSV55449541; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1259211052; called by muse, mutect2, varscan2
- MYO18B | c.7591C>T p.P2531S | Missense Mutation (SNP) | VAF 494/634 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV59149632; called by muse, varscan2
- MYO18B | c.7619G>A p.R2540Q | Missense Mutation (SNP) | VAF 124/570 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs749740047, COSV100123020; called by muse, varscan2
- MYO1H | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 348/349 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1425604047, COSV100183482, COSV99081637; called by muse, mutect2, varscan2
- NAALADL1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371781219; called by muse, mutect2, varscan2
- NBAS | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1337326154; called by muse, varscan2
- NBEA | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 195/359 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267603808, COSV59766496, COSV59830102; called by muse, mutect2, varscan2
- NBEA | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 154/270 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV59805786; called by muse, mutect2, varscan2
- NCOA6 | c.6176G>A p.R2059Q | Missense Mutation (SNP) | VAF 28/581 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1191558154, COSV62868558; called by muse, mutect2
- NCR2 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 362/471 reads (77%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753979828, COSV66100665; called by muse, mutect2, varscan2
- NDN | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 222/503 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs763474594, COSV59361197; called by muse, mutect2, varscan2
- NDUFA11 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 126/386 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs772849772; called by muse, mutect2, varscan2
- NEB | c.8026G>A p.E2676K | Missense Mutation (SNP) | VAF 110/346 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1460283559; called by muse, mutect2, varscan2
- NEFM | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 402/404 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204258828; called by muse, mutect2, varscan2
- NELL1 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.852); catalogued as rs1312307752; called by muse, mutect2, varscan2
- NKD2 | c.201G>A p.Q67= | Splice Region (SNP) | VAF 242/414 reads (58%) | catalogued as COSV56890936; called by muse, mutect2, varscan2
- NLRP10 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 378/451 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755155590, COSV60778802; called by muse, mutect2, varscan2
- NLRP14 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 128/176 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as rs867695793; called by muse, mutect2, varscan2
- NLRP3 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 417/419 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs104895414, CM071602, COSV60231611; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 150/340 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56710757; called by muse, mutect2, varscan2
- NLRP5 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 129/338 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs1200452996, COSV66761780; called by muse, mutect2, varscan2
- NOTCH3 | c.6878C>T p.P2293L | Missense Mutation (SNP) | VAF 285/599 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54630048; called by muse, mutect2, varscan2
- NOTCH3 | c.3074C>G p.P1025R | Missense Mutation (SNP) | VAF 256/560 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV54630897, COSV54634871; called by muse, mutect2, varscan2
- NRXN1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 94/528 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489429289; called by muse, mutect2, varscan2
- NSUN7 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57276272; called by muse, mutect2, varscan2
- NTM | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66177919; called by muse, mutect2, varscan2
- NTRK3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 240/429 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1395756451, COSV62298363; called by muse, mutect2, varscan2
- NWD2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100519736; called by muse, mutect2, varscan2
- OBSCN | c.8900G>A p.G2967D | Missense Mutation (SNP) | VAF 611/612 reads (100%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs367712031; called by muse, varscan2
- OFD1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 412/413 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs748643730; called by muse, mutect2, varscan2
- OLFM2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 219/461 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.158); catalogued as rs756244167; called by muse, mutect2, varscan2
- OR10A3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs866622532, COSV62459092; called by muse, mutect2, varscan2
- OR10C1 | c.38T>G p.F13C (on ENST00000622521; = p.F11C on NM_013941.3) | Missense Mutation (SNP) | VAF 112/647 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65822494; called by muse, mutect2, varscan2
- OR12D3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 103/641 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1298594837; called by muse, mutect2, varscan2
- OR1N1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 369/370 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs778357078, COSV59197039; called by muse, mutect2, varscan2
- OR1Q1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 434/435 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52917616; called by muse, mutect2, varscan2
- OR2A12 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 134/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1437273108; called by muse, mutect2, varscan2
- OR2A25 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781251490, COSV68716866, COSV68716922; called by muse, mutect2, varscan2
- OR2A25 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as COSV68717029; called by muse, mutect2, varscan2
- OR2D2 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55057547; called by muse, mutect2, varscan2
- OR2T2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 529/1151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760149658, COSV61617769; called by muse, mutect2, varscan2
- OR4B1 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58882054; called by muse, mutect2, varscan2
- OR4C5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as rs918149366, COSV60563452; called by muse, mutect2, varscan2
- OR4E1 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs546907185; called by muse, mutect2, varscan2
- OR4K13 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1566530921, COSV59860862; called by muse, mutect2, varscan2
- OR4K15 | c.701C>T p.S234F (on ENST00000305051; = p.S210F on NM_001005486.1) | Missense Mutation (SNP) | VAF 124/245 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV59300274; called by muse, mutect2, varscan2
- OR4K17 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1311596870, COSV100210616; called by muse, mutect2, varscan2
- OR4N2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 168/352 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV60054844; called by muse, mutect2, varscan2
- OR4Q3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177294; called by muse, mutect2, varscan2
- OR4X1 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 287/389 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs754663946, COSV60724281; called by muse, mutect2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 195/256 reads (76%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR52A1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV61093038; called by muse, mutect2, varscan2
- OR52K2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 258/329 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs766771557; called by muse, mutect2, varscan2
- OR52R1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 249/318 reads (78%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as rs370070710, COSV61887659; called by muse, mutect2, varscan2
- OR56A4 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 258/330 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1360583886; called by muse, mutect2, varscan2
- OR56B1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 88/365 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV57723733; called by muse, mutect2, varscan2
- OR5AP2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 309/310 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57257668; called by muse, varscan2
- OR8D2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 94/95 reads (99%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100659130, COSV62488279; called by muse, mutect2, varscan2
- OSBPL7 | c.810T>G p.H270Q | Missense Mutation (SNP) | VAF 233/365 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50106980; called by muse, mutect2, varscan2
- OTOG | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 208/263 reads (79%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1447677589; called by muse, mutect2, varscan2
- OXCT2 | c.1529G>A p.R510K | Missense Mutation (SNP) | VAF 118/799 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765862292; called by muse, mutect2
- P2RX4 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs750261530; called by muse, mutect2, varscan2
- PAK5 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 277/333 reads (83%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.888); catalogued as rs1262495622, COSV62022080; called by muse, mutect2, varscan2
- PAPPA | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 502/503 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60286958; called by muse, mutect2, varscan2
- PAPPA2 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 386/387 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV62773428; called by muse, mutect2, varscan2
- PAPPA2 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 280/281 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as rs191519115; called by muse, mutect2, varscan2
- PARP16 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 299/525 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99975407; called by muse, mutect2, varscan2
- PASK | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 321/495 reads (65%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52148063; called by muse, mutect2, varscan2
- PAX8 | c.192G>C p.R64S | Missense Mutation (SNP) | VAF 250/338 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54507484; called by muse, mutect2, varscan2
- PCARE | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 339/444 reads (76%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as COSV59053684, COSV59058707; called by muse, mutect2, varscan2
- PCDH17 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 210/389 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931783, COSV64973397; called by muse, mutect2, varscan2
- PCDHA3 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs1554122639; called by muse, mutect2, varscan2
- PCDHB11 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 264/740 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.234); catalogued as rs1554285622; called by muse, varscan2
- PCDHB12 | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 155/569 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs782479486; called by muse, mutect2, varscan2
- PCDHB4 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 181/604 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs146284769; called by muse, mutect2, varscan2
- PCDHGA2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); catalogued as COSV53925127; called by muse, mutect2, varscan2
- PCDHGA9 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 186/282 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs377389968; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 187/311 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCK2 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV53751092; called by mutect2, varscan2
- PCLO | c.7262C>T p.P2421L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1196374147; called by muse, mutect2, varscan2
- PCLO | c.6454G>A p.E2152K | Missense Mutation (SNP) | VAF 111/189 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61636627; called by muse, mutect2, varscan2
- PCLO | c.5621C>T p.P1874L | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371631647, COSV61631945; called by muse, mutect2, varscan2
- PCLO | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.085); catalogued as COSV61620963; called by muse, mutect2, varscan2
- PCNT | c.8562A>C p.K2854N | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.421); catalogued as COSV100855449; called by muse, mutect2, varscan2
- PCSK1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1439220661; called by muse, mutect2, varscan2
- PCSK6 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 161/300 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323235197, COSV59342913; called by muse, mutect2, varscan2
- PDE11A | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 241/351 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.207); catalogued as rs539536729, COSV53706005; called by muse, mutect2, varscan2
- PDE4DIP | c.5649G>A p.R1883= | Splice Region (SNP) | VAF 117/118 reads (99%) | catalogued as rs1282280555, COSV57711888; called by muse, mutect2, varscan2
- PEAK1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs763796402; called by muse, mutect2, varscan2
- PFKFB1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 233/233 reads (100%) | PolyPhen benign (0.054); catalogued as rs150213595, COSV66628924; called by muse, mutect2, varscan2
- PGK2 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 494/799 reads (62%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); catalogued as COSV59164877; called by muse, mutect2, varscan2
- PIEZO2 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 464/464 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1486015917; called by muse, varscan2
- PIK3C2G | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 315/315 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV56819107; called by muse, mutect2, varscan2
- PIM3 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 62/934 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV62259508; called by muse, mutect2
- PIMREG | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.301); catalogued as rs1254336242; called by muse, mutect2, varscan2
- PKD2L1 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 672/672 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs147259519; called by muse, mutect2, varscan2
- PKDREJ | c.6434G>A p.R2145K | Missense Mutation (SNP) | VAF 103/612 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV99478526; called by muse, mutect2, varscan2
- PKHD1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 150/570 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM149115, COSV100581071, COSV61882957; called by muse, mutect2, varscan2
- PKHD1 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 52/598 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142608481; ClinVar: uncertain significance; called by muse, mutect2
- PKHD1L1 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 237/533 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1185554521, COSV65738242, COSV65742422; called by muse, mutect2, varscan2
- PKHD1L1 | c.8437C>G p.P2813A | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV65743098; called by muse, mutect2, varscan2
- PLB1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 50/323 reads (15%) | catalogued as COSV59832507; called by muse, mutect2, varscan2
- PLCH1 | c.4007C>T p.S1336F (on ENST00000340059 / NM_001130960.2; = p.S1328F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 423/424 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.317); catalogued as COSV100397973; called by muse, mutect2, varscan2
- PLEKHA7 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201494675, COSV63046349; called by muse, mutect2, varscan2
- PLXDC2 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 121/122 reads (99%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs1416218731; called by muse, mutect2, varscan2
- PLXNA4 | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 550/726 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58126734; called by muse, mutect2, varscan2
- PLXNB1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 638/639 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761471990; called by muse, mutect2, varscan2
- PNLIP | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 297/298 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866345576, COSV100981593, COSV65040597, COSV65041391; called by muse, mutect2, varscan2
- POLI | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 256/256 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs369815747, COSV99471159; called by muse, mutect2, varscan2
- POM121L12 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 216/606 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.267); catalogued as rs746047304, COSV68692144; called by muse, mutect2, varscan2
- POTEE | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV100387802, COSV58230646; called by muse, mutect2, varscan2
- POTEG | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 86/1298 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1190367003; called by muse, mutect2
- POU3F3 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 556/747 reads (74%) | catalogued as COSV63721611; called by muse, mutect2
- PPFIA1 | c.3218T>C p.I1073T | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs149188477; called by muse, mutect2, varscan2
- PPFIA2 | c.3057G>A p.M1019I | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100335233; called by muse, mutect2, varscan2
- PPFIA2 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1449867428; called by muse, mutect2, varscan2
- PPP1R2B | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV70372837; called by muse, mutect2, varscan2
- PPP1R3A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1275417952, COSV52879106, COSV52880839; called by muse, mutect2, varscan2
- PPP4R4 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 258/373 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1261351555; called by muse, mutect2, varscan2
- PRAMEF1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 226/405 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV60007495; called by muse, mutect2, varscan2
- PRAMEF11 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 565/975 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.187); catalogued as rs773211732, COSV101463306; called by muse, mutect2, varscan2
- PRAMEF12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs752095583, COSV63215039; called by muse, mutect2, varscan2
- PRAMEF2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 422/716 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1063791; called by muse, mutect2, varscan2
- PRB2 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 526/596 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV66982042; called by muse, varscan2
- PRDM9 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV57002253, COSV57005862; called by muse, varscan2
- PRDM9 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 128/240 reads (53%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV57013336, COSV99690363; called by muse, varscan2
- PREX1 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 440/605 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs780759564; called by muse, mutect2, varscan2
- PRKAA2 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64801684; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PRR30 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 370/497 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.368); catalogued as rs1271614694; called by muse, mutect2, varscan2
- PRSS55 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 471/471 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1328290170; called by muse, varscan2
- PRSS57 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 293/566 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.102); catalogued as rs575963662; called by muse, mutect2, varscan2
- PRUNE2 | c.6974C>T p.S2325F | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV65042576; called by muse, mutect2, varscan2
- PRUNE2 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV65029878; called by muse, mutect2, varscan2
- PSG2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 259/441 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs376432612; called by muse, mutect2, varscan2
- PSMD5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 591/591 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52960217; called by muse, mutect2, varscan2
- PSMG1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59001460; called by muse, mutect2, varscan2
- PTPN4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 159/241 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1186373089, COSV55298093, COSV99750484; called by muse, mutect2, varscan2
- PTPN9 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 224/553 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV100144445; called by muse, mutect2, varscan2
- PTPRB | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 286/293 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1220260066; called by muse, varscan2
- PTPRC | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 348/349 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs748511747, COSV61409994; called by muse, mutect2, varscan2
- PTPRD | c.4506+1G>A p.X1502_splice | Splice Site (SNP) | VAF 209/209 reads (100%) | catalogued as rs1356752980; called by muse, mutect2, varscan2
- PTPRH | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 110/308 reads (36%) | catalogued as rs142263222; called by muse, mutect2, varscan2
- PTPRS | c.5318C>T p.S1773L | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779302415, COSV53619781; called by muse, mutect2, varscan2
- PTPRT | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 461/608 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV62013512; called by muse, mutect2, varscan2
- RAG1 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 337/430 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs866862677, COSV55025161; called by muse, mutect2, varscan2
- RANGAP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 97/816 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as rs746265231, COSV62363557; called by muse, mutect2, varscan2
- RASAL1 | c.732G>A p.G244= | Splice Region (SNP) | VAF 178/178 reads (100%) | catalogued as rs145345802; called by muse, mutect2, varscan2
- RASGEF1C | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs774080726; called by muse, mutect2, varscan2
- RBM23 | c.358C>T p.R120C (on ENST00000359890 / NM_001077351.2; = p.R104C on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/239 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs761437876, COSV57127804; called by muse, varscan2
- RELN | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as rs762608682, COSV59002828; called by muse, mutect2, varscan2
- RLF | c.4609C>T p.L1537F | Missense Mutation (SNP) | VAF 354/605 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV65653340; called by muse, mutect2, varscan2
- RP1 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 200/307 reads (65%) | catalogued as COSV101587851, COSV73138824; called by muse, mutect2, varscan2
- RSPH14 | c.792G>A p.G264= | Splice Region (SNP) | VAF 432/577 reads (75%) | catalogued as COSV53267250; called by muse, mutect2, varscan2
- RYR1 | c.6185G>A p.R2062H | Missense Mutation (SNP) | VAF 148/385 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs368235923; called by muse, mutect2, varscan2
- SAFB | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as COSV52652238; called by muse, mutect2, varscan2
- SALL1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 505/506 reads (100%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); catalogued as COSV51761770; called by muse, mutect2, varscan2
- SBF2 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs770723203, COSV56302182; called by muse, mutect2, varscan2
- SCN10A | c.5587C>T p.R1863W | Missense Mutation (SNP) | VAF 398/400 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370779258; called by muse, varscan2
- SCN3A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 244/354 reads (69%) | catalogued as COSV51820116; called by muse, mutect2, varscan2
- SCUBE2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1244271281, CM124525; called by muse, mutect2, varscan2
- SDK2 | c.4642G>A p.G1548R | Missense Mutation (SNP) | VAF 149/488 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV66187267; called by muse, mutect2, varscan2
- SERPINA1 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 183/752 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs551595739; called by muse, mutect2, varscan2
- SERPINB10 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539628633; called by muse, mutect2, varscan2
- SEZ6L | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 556/711 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99962780; called by muse, mutect2, varscan2
- SF3B1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 212/340 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV59211931, COSV59212622; called by muse, mutect2, varscan2
- SGSM1 | c.2587G>A p.E863K (on ENST00000400359 / NM_001039948.4; = p.E802K on NM_133454.3) | Missense Mutation (SNP) | VAF 602/778 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs764241355; called by muse, mutect2, varscan2
- SH3RF2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV63041224; called by muse, mutect2, varscan2
- SHANK1 | c.5534G>A p.G1845D | Missense Mutation (SNP) | VAF 197/562 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs1482432260; called by muse, mutect2, varscan2
- SHANK1 | c.4196C>T p.A1399V | Missense Mutation (SNP) | VAF 160/492 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1280923316; called by muse, varscan2
- SIRPB1 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 49/447 reads (11%) | catalogued as rs148690008; called by muse, mutect2, varscan2
- SIRPB1 | c.435C>T p.A145= | Splice Region (SNP) | VAF 48/509 reads (9%) | catalogued as rs1246171795, COSV53541523; called by muse, mutect2
- SIX2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 400/513 reads (78%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.093); catalogued as rs766312512; called by muse, mutect2, varscan2
- SKOR2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1226917240; called by muse, mutect2, varscan2
- SLC12A8 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 440/441 reads (100%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs918768903; called by muse, mutect2, varscan2
- SLC13A5 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 213/298 reads (71%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV53425596; called by muse, mutect2, varscan2
- SLC17A3 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 368/446 reads (83%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as rs377515468; called by muse, varscan2
- SLC17A6 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs138159912, COSV54138373; called by muse, mutect2, varscan2
- SLC18A3 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 162/502 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as rs761770195; called by muse, mutect2, varscan2
- SLC25A51 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 436/448 reads (97%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs1426256604; called by muse, mutect2, varscan2
- SLC27A6 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 136/225 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867556415, COSV99064213; called by muse, mutect2, varscan2
- SLC36A2 | c.762C>G p.S254R | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV58862854; called by muse, mutect2
- SLC39A12 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV66194567, COSV66195394; called by muse, mutect2, varscan2
- SLC4A10 | c.2048G>A p.W683* (on ENST00000446997 / NM_001354461.2; = p.W653* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 113/400 reads (28%) | catalogued as COSV55791768; called by muse, mutect2, varscan2
- SLC4A3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 231/348 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1052409928; called by muse, mutect2, varscan2
- SLC6A18 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 315/538 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219905024, COSV57250514; called by muse, mutect2, varscan2
- SLC8A1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 343/432 reads (79%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs763896494; called by muse, mutect2, varscan2
- SLC8B1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV52526571; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1969G>A p.D657N (on ENST00000540229 / NM_001371097.1; = p.D596N on NM_001009562.4) | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67441947; called by muse, mutect2, varscan2
- SLITRK6 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1243884063, COSV68389758, COSV68391125; called by muse, mutect2, varscan2
- SMYD1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 435/581 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs866274358, COSV70226047; called by muse, mutect2, varscan2
- SNCAIP | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 388/514 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775708743, COSV54420188; called by muse, mutect2, varscan2
- SNTG1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 110/433 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV52427270; called by muse, mutect2, varscan2
- SNTG2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV58009297; called by muse, mutect2, varscan2
- SORL1 | c.759-1G>A p.X253_splice | Splice Site (SNP) | VAF 60/60 reads (100%) | catalogued as rs1377408732; called by muse, mutect2, varscan2
- SOWAHA | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1475147659; called by muse, mutect2, varscan2
- SPAG1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs928977296; called by muse, mutect2, varscan2
- SPAG17 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 222/338 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1201454411, COSV60461015; called by muse, mutect2, varscan2
- SPANXN5 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV64968884; called by muse, mutect2, varscan2
- SPATS2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as COSV58923434; called by muse, mutect2, varscan2
- SPDYE4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.865); catalogued as rs748791171, COSV100171295, COSV100171308; called by muse, mutect2, varscan2
- SPEG | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 174/598 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1170905232, COSV56665041; called by muse, mutect2, varscan2
- SPEG | c.8470C>T p.P2824S | Missense Mutation (SNP) | VAF 139/443 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56662195; called by muse, mutect2, varscan2
- SPHKAP | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 345/476 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754167845, COSV60871584; called by muse, mutect2, varscan2
- SPINT1 | c.1342G>A p.D448N (on ENST00000344051 / NM_181642.3; = p.D432N on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/443 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1418820560; called by muse, mutect2, varscan2
- SPRR2A | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 466/499 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV66991481; called by muse, mutect2, varscan2
- SPRR3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 425/426 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); catalogued as rs867801692, COSV54878625; called by muse, mutect2, varscan2
- SPRYD7 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 125/226 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1190456570; called by muse, mutect2, varscan2
- SPTA1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 379/380 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148714399, COSV63754963; called by muse, mutect2, varscan2
- SRRM2 | c.7204C>T p.L2402F | Missense Mutation (SNP) | VAF 630/631 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs754776293; called by muse, mutect2, varscan2
- SSTR3 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 599/807 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100142881; called by muse, mutect2, varscan2
- ST14 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 203/204 reads (100%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs760337264; called by muse, varscan2
- ST18 | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 105/397 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV99389435; called by muse, mutect2, varscan2
- STARD9 | c.3767C>T p.P1256L | Missense Mutation (SNP) | VAF 318/590 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs1052615840; called by muse, mutect2, varscan2
- STAT5B | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 232/326 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs1269922038, COSV53184270, COSV53185067, COSV99510639; called by muse, mutect2, varscan2
- STEAP4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57328130, COSV57331236; called by muse, mutect2, varscan2
- STK31 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 188/346 reads (54%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV63456069; called by muse, mutect2, varscan2
- STON1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 111/489 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59139597; called by muse, mutect2, varscan2
- STXBP5L | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV56525292; called by muse, mutect2, varscan2
- SULT1B1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60208278; called by muse, mutect2, varscan2
- SUPT20H | c.890C>T p.P297L (on ENST00000350612 / NM_001014286.3; = p.P298L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs200732187; called by muse, mutect2, varscan2
- SYBU | c.1988C>T p.T663I (on ENST00000276646 / NM_001099754.2; = p.T662I on NM_017786.6) | Missense Mutation (SNP) | VAF 138/317 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs774840003; called by muse, mutect2, varscan2
- SYDE1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 224/489 reads (46%) | catalogued as rs1237432733; called by muse, mutect2, varscan2
- SYMPK | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 166/311 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs943389564; called by muse, mutect2, varscan2
- SYNJ2BP | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 187/261 reads (72%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as rs772822266, COSV56445891; called by muse, mutect2, varscan2
- SYT10 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 223/224 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99952205; called by muse, mutect2, varscan2
- SYT12 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 462/464 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as COSV67355519; called by muse, mutect2, varscan2
- SYT16 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 203/294 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374283682, COSV101413525; called by muse, varscan2
- SYT3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs866261528, COSV58899319; called by muse, mutect2, varscan2
- TAF6 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59844086; called by muse, mutect2, varscan2
- TAS2R60 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 129/494 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812355, COSV60330541; called by muse, varscan2
- TBXT | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 459/460 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs753100833, COSV51616429; called by muse, mutect2, varscan2
- TCHHL1 | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs1184509503, COSV64287046; called by muse, mutect2, varscan2
- TENM2 | c.3655C>T p.R1219C (on ENST00000518659 / NM_001122679.2; = p.R987C on NM_001080428.3) | Missense Mutation (SNP) | VAF 99/337 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371063467; called by muse, mutect2, varscan2
- TENT5D | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 233/234 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57638844; called by muse, mutect2, varscan2
- THEG | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 110/329 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1378700394, COSV100700587; called by muse, mutect2, varscan2
- THSD7B | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 121/393 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs754916507, COSV55714925; called by muse, mutect2, varscan2
- TINAG | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 390/681 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52510057, COSV99448496; called by muse, mutect2, varscan2
- TLL1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 331/332 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV50281947; called by muse, mutect2, varscan2
- TLR8 | c.1694C>T p.S565L (on ENST00000218032 / NM_138636.5; = p.S583L on NM_016610.4) | Missense Mutation (SNP) | VAF 218/219 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV54316657; called by muse, mutect2, varscan2
- TMC2 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 320/388 reads (82%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs141505256; called by muse, mutect2, varscan2
- TMEM63C | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs577654792; called by muse, mutect2, varscan2
- TMPRSS15 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1338875221; called by muse, mutect2, varscan2
- TMPRSS7 | c.592G>A p.A198T (on ENST00000452346; = p.A85T on NM_001042575.2) | Missense Mutation (SNP) | VAF 400/400 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs866247414; called by muse, mutect2, varscan2
- TNXB | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 369/493 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs563472994, COSV64479134; called by muse, mutect2, varscan2
- TOMM7 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 161/307 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100626941; called by muse, mutect2
- TPH1 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV51457280; called by muse, mutect2, varscan2
- TPH2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 341/342 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs773096016, COSV61591462, COSV61593532, COSV61594165; called by muse, mutect2, varscan2
- TPST2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 621/806 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV58679171; called by muse, mutect2, varscan2
- TPTE | c.569G>A p.W190* (on ENST00000618007 / NM_199261.4; = p.W172* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as rs1255334410; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770983552; called by muse, mutect2, varscan2
- TRAV6 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1213744651; called by muse, mutect2, varscan2
- TRHR | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 198/372 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.045); catalogued as COSV61233422; called by muse, mutect2, varscan2
- TRIM35 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 363/363 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369310263; called by muse, varscan2
- TRIOBP | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 617/821 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs370108541; called by muse, mutect2, varscan2
- TRO | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs748221975; called by muse, mutect2, varscan2
- TRPM5 | c.1817G>A p.W606* | Nonsense Mutation (SNP) | VAF 80/466 reads (17%) | catalogued as rs1440522343; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 432/433 reads (100%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1440851175, COSV62507013, COSV62510751; called by muse, mutect2, varscan2
- TRPM8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 186/322 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs919281308, COSV100224345; called by muse, mutect2, varscan2
- TSHB | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 174/613 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199873661; called by muse, mutect2, varscan2
- TSPEAR | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 393/394 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs782375762; called by muse, mutect2, varscan2
- TSPOAP1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 173/546 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52104641; called by muse, mutect2, varscan2
- TSSK1B | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 242/396 reads (61%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs374467859; called by muse, varscan2
- TSSK3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 362/630 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs770319759, COSV100344936, COSV61982706; called by muse, mutect2, varscan2
- TTBK1 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 154/728 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV99444230; called by muse, mutect2, varscan2
- TTBK1 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 192/798 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1158098886; called by muse, mutect2
- TTN | c.73808A>G p.N24603S (on ENST00000591111; = p.N17179S on NM_003319.4) | Missense Mutation (SNP) | VAF 273/411 reads (66%) | PolyPhen benign (0.164); catalogued as COSV100588455; called by muse, mutect2, varscan2
- TTN | c.53189C>T p.S17730L (on ENST00000591111; = p.S10306L on NM_003319.4) | Missense Mutation (SNP) | VAF 136/446 reads (30%) | PolyPhen probably damaging (0.996); catalogued as COSV60386013; called by muse, mutect2, varscan2
- TTN | c.48730G>A p.E16244K (on ENST00000591111; = p.E8820K on NM_003319.4) | Missense Mutation (SNP) | VAF 229/372 reads (62%) | PolyPhen benign (0.036); catalogued as CM1413537; called by muse, mutect2, varscan2
- TTN | c.38746G>A p.D12916N (on ENST00000591111; = p.D5492N on NM_003319.4) | Missense Mutation (SNP) | VAF 170/537 reads (32%) | PolyPhen benign (0.003); catalogued as rs794729431, COSV60181732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28907G>A p.G9636D (on ENST00000591111; = p.G8709D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 322/466 reads (69%) | PolyPhen probably damaging (0.959); catalogued as rs1201726118; called by muse, varscan2
- TTN | c.20962G>A p.E6988K (on ENST00000591111; = p.E6061K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 308/513 reads (60%) | PolyPhen benign (0.099); catalogued as rs867359588, COSV60255234; called by muse, mutect2, varscan2
- TTN | c.18071C>T p.S6024L (on ENST00000591111; = p.S5097L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/429 reads (36%) | PolyPhen benign (0.306); catalogued as rs868170582, COSV59965477, COSV60280617; called by muse, mutect2, varscan2
- TTN | c.6322G>A p.E2108K (on ENST00000591111; = p.E2062K on NM_003319.4) | Missense Mutation (SNP) | VAF 140/466 reads (30%) | PolyPhen probably damaging (0.994); catalogued as rs762999586, COSV60013101; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TUBA3C | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 191/706 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV67139954; called by muse, mutect2, varscan2
- TUFM | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 381/383 reads (99%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV57949647; called by muse, mutect2, varscan2
- TYK2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 115/221 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53385795; called by muse, mutect2, varscan2
- UBQLN3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756923573; called by muse, mutect2, varscan2
- UGT1A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 311/475 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100529910; called by muse, mutect2, varscan2
- UGT2B17 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV58501062; called by muse, mutect2, varscan2
- UMODL1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV68558172; called by muse, mutect2, varscan2
- UNC13C | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs547772270; called by muse, mutect2, varscan2
- UNC13C | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 248/416 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as rs1425768653; called by muse, mutect2, varscan2
- UNC13C | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52923813; called by muse, mutect2, varscan2
- UNC13C | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 202/385 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs768039530, COSV52841291, COSV52849785; called by muse, mutect2, varscan2
- UNC5B | c.1773C>T p.L591= | Splice Region (SNP) | VAF 259/259 reads (100%) | catalogued as COSV58974670; called by muse, mutect2, varscan2
- UNC79 | c.2525C>T p.P842L (on ENST00000393151 / NM_001346218.2; = p.P665L on NM_020818.5) | Missense Mutation (SNP) | VAF 276/510 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760074934, COSV56372105; called by muse, varscan2
- UNC93B1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 418/437 reads (96%) | SIFT tolerated (0.27); PolyPhen benign (0.343); catalogued as COSV99916326; called by muse, varscan2
- USP26 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 342/344 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as rs748525921, COSV100896537; called by muse, varscan2
- USP29 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 171/455 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954305714, COSV54143387; called by muse, mutect2, varscan2
- USP36 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 318/382 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549596089; called by muse, mutect2, varscan2
- VAV1 | c.207C>T p.F69= | Splice Region (SNP) | VAF 92/236 reads (39%) | catalogued as rs780489736; called by muse, mutect2, varscan2
- VCP | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 300/302 reads (99%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV62720892; called by muse, varscan2
- VN1R2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV59038143; called by muse, varscan2
- VPS13B | c.10928C>T p.A3643V | Missense Mutation (SNP) | VAF 185/297 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100661029, COSV62142496; called by muse, mutect2, varscan2
- VPS13C | c.1706G>A p.G569E (on ENST00000644861 / NM_020821.3; = p.G526E on NM_017684.5) | Missense Mutation (SNP) | VAF 217/381 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51164954; called by muse, mutect2, varscan2
- VWA3B | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 205/288 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs779891369; called by muse, varscan2
- VWA5B2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 452/453 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs745339755, COSV56610795, COSV56613561; called by muse, mutect2, varscan2
- VWC2L | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 135/431 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56980813; called by muse, mutect2, varscan2
- WDFY4 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 167/477 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs148176877, COSV57427113; called by muse, mutect2, varscan2
- WDFY4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 260/410 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747294517; called by muse, mutect2, varscan2
- WDR17 | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 358/359 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54581765; called by muse, mutect2, varscan2
- WDR19 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 91/478 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs780714075; called by muse, mutect2, varscan2
- WDR87 | c.7090G>A p.E2364K | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs1327970043, COSV58202457; called by muse, mutect2, varscan2
- WDR87 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 235/408 reads (58%) | catalogued as rs975234445; called by muse, mutect2, varscan2
- WDR93 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 356/648 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs749743648; called by muse, mutect2, varscan2
- WRN | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 406/407 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs761819112, COSV53298883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WRNIP1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 361/993 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1047032263; called by muse, mutect2, varscan2
- WWC1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 165/226 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368175149; called by muse, varscan2
- XDH | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.627); catalogued as rs763648123, COSV65150178; called by muse, varscan2
- XIRP2 | c.1905G>A p.W635* (on ENST00000628543; = p.W810* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 247/369 reads (67%) | catalogued as rs1285230507; called by muse, varscan2
- XKR5 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199717191; called by muse, mutect2, varscan2
- ZBTB47 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 669/670 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs951511200; called by muse, mutect2, varscan2
- ZC3H3 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 516/905 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs778193896; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 307/456 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868038766; called by muse, mutect2, varscan2
- ZFHX4 | c.6025C>T p.P2009S | Missense Mutation (SNP) | VAF 346/664 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99259321; called by muse, mutect2, varscan2
- ZFP92 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 221/222 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV58599140; called by muse, mutect2, varscan2
- ZMYM2 | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 55/281 reads (20%) | catalogued as COSV67033372; called by muse, mutect2, varscan2
- ZNF177 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs758925650; called by muse, mutect2, varscan2
- ZNF18 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 311/452 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1304184948, COSV59552405; called by muse, mutect2, varscan2
- ZNF260 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 236/407 reads (58%) | catalogued as rs182026084; called by muse, mutect2, varscan2
- ZNF281 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 363/363 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV54166142; called by muse, mutect2, varscan2
- ZNF285 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 126/340 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58408412; called by muse, mutect2, varscan2
- ZNF335 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 448/546 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780577772, COSV59817450; called by muse, mutect2, varscan2
- ZNF445 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 309/310 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68539273; called by muse, mutect2, varscan2
- ZNF501 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 452/452 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV68516136; called by muse, mutect2, varscan2
- ZNF528 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 146/459 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100846682; called by muse, mutect2, varscan2
- ZNF574 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 250/459 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99726486; called by muse, mutect2, varscan2
- ZNF578 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 255/405 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV69737524; called by muse, mutect2, varscan2
- ZNF594 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 216/279 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs779743392; called by muse, mutect2, varscan2
- ZNF665 | c.325C>T p.R109* (on ENST00000600412; = p.R174* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 157/358 reads (44%) | catalogued as rs1042133945; called by muse, mutect2, varscan2
- ZNF676 | c.1124G>A p.G375E (on ENST00000650058; = p.G343E on NM_001001411.3) | Missense Mutation (SNP) | VAF 262/737 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101236211, COSV68094205, COSV68095102; called by muse, mutect2, varscan2
- ZNF699 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 245/538 reads (46%) | catalogued as rs145027997, COSV58026240; called by muse, mutect2, varscan2
- ZNF699 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 229/472 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100426862; called by muse, mutect2, varscan2
- ZNF737 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs782305873, COSV101417654; called by muse, mutect2, varscan2
- ZNF793 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 199/337 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs749691796, COSV101495686; called by muse, mutect2, varscan2
- ZNF836 | c.1889G>T p.R630I | Missense Mutation (SNP) | VAF 66/523 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774948714, COSV100440501, COSV59080964; called by muse, mutect2, varscan2
- ZNF860 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 503/505 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1269400386; called by muse, mutect2, varscan2
- ZSCAN18 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 307/495 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV53729236, COSV53736040; called by muse, mutect2, varscan2
- ZSCAN18 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs1446791363; called by muse, mutect2, varscan2
- ZSCAN5A | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 116/203 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1188499793; called by muse, mutect2, varscan2
- ABCB1 | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ABCC4 | c.3707A>G p.N1236S | Missense Mutation (SNP) | VAF 178/320 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ABCD4 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ABR | c.1174C>T p.Q392* (on ENST00000302538 / NM_021962.5; = p.Q355* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 113/245 reads (46%) | called by muse, mutect2, varscan2
- AC098582.1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 70/158 reads (44%) | called by muse, mutect2, varscan2
- AC244517.10 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 178/271 reads (66%) | PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- ACAD10 | c.2395G>A p.V799I | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ACAN | c.4934G>A p.G1645D | Missense Mutation (SNP) | VAF 185/465 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACD | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 610/612 reads (100%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSBG1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 285/545 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ACSM6 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 290/291 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ACSS3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 251/252 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTL8 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 389/650 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM30 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 144/651 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAM32 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 323/326 reads (99%) | SIFT tolerated (0.23); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ADAMTS13 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 490/491 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ADAMTS7 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 213/521 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ADAMTS8 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGRA1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ADGRF3 | c.3037G>A p.G1013S (on ENST00000311519 / NM_001145168.1; = p.G814S on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRV1 | c.10619C>A p.S3540Y | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- ADRA1A | c.419_429del p.Q140Pfs*157 | Frame Shift Del (DEL) | VAF 54/476 reads (11%) | called by mutect2, pindel
- ADSS1 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 153/282 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGRN | c.3596C>T p.S1199F | Missense Mutation (SNP) | VAF 379/655 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- AHDC1 | c.4580C>T p.P1527L | Missense Mutation (SNP) | VAF 331/822 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AHDC1 | c.4579C>T p.P1527S | Missense Mutation (SNP) | VAF 333/821 reads (41%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AL121899.2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 499/595 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AL645922.1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 172/693 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ALAD | c.836_837del p.S279Wfs*16 | Frame Shift Del (DEL) | VAF 354/564 reads (63%) | called by pindel, varscan2
1,400 further variants in this file (615 protein-altering or splice-affecting, 685 silent, 100 other) are not listed here.
